MMRF case MMRF_2230 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/21c32fd0-13b2-4e72-8697-65180aa9edc9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.3 years (24,595 days); ISS stage: I; Days to last known disease status: 157 days; Days to last follow up: 157 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 64 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 124 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 0): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 17.8 mg/dL; Immunoglobulin G 31.6 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 2.9 µg/mL; Hemoglobin 8.31 mmol/L; Leukocytes 8.19 ×10⁹/L; Absolute Neutrophil 5.14 ×10⁹/L; Platelets 298 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.6 mmol/L; Albumin 42 g/L; Total Protein 8.5 g/dL; Glucose 5.72 mmol/L.
- Day 81 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.87 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.53 g/L; Beta 2 Microglobulin 3.8 µg/mL; Hemoglobin 5.21 mmol/L; Leukocytes 7.47 ×10⁹/L; Absolute Neutrophil 6.37 ×10⁹/L; Platelets 276 ×10⁹/L; Creatinine 142 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 5.8 g/dL; Glucose 6.11 mmol/L.
- Day 157 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.49 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 2.5 µg/mL; Hemoglobin 7.38 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.24 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Glucose 6 mmol/L.

Other clinical attributes
- Day -13: Weight: 78 kg; Height: 154 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2230_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_2230_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
